Surgical pathology report (de-identified scan), TCGA case TCGA-B9-A8YH, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-A8YH-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

CHX ICD O-3
Carcinoma, papillary renal
cell 8260/3
Carcinoma, papillary NOS
8050/3
Site (R) Kidney NOS
C64.9
4/11/14

Diagnosis:

A: Kidney, right, robotic partial nephrectomy

Laterality: right

Histologic tumor type/subtype: papillary carcinoma, type I

Sarcomatoid features: absent

Histologic grade (if applicable): grade 2 (Fuhrman)

Tumor size (greatest dimension): 3.0 x 2.7 x 2.0 cm

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota' s fascia: not identified

Renal sinus: not applicable

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): negative for malignancy

Renal capsular margin (partial nephrectomy only): negative for malignancy

Paranephric adipose tissue margin (partial nephrectomy only): negative for malignancy

AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old male with right renal mass.

[page 2 of 3]
Gross Description:

Received is one appropriately labeled container, additionally labeled "right renal mass" and consists of a 13 gram (3.1 x 2.9 x 2.7 cm) partial nephrectomy. The capsule is intact pink/tan, smooth with a scant amount of attached adipose tissue. The capsule is inked blue and the parenchymal margin is inked black. The cut surface has a 3.0 x 2.7 x 2.0 cm well-circumscribed soft variegated mass that bulges the capsule but does not extend through it and grossly abuts the parenchymal margin. The mass occupies approximately 90% of the specimen and approximately 10% hemorrhage and necrosis. A portion of the mass is given to tumor procurement foundation. A perpendicular section with respect to the capsule and parenchymal margin in A1-A5.

*Per TSS dx discrepancy form, TCGA
tumor is papillary renal cell carcinoma.*

Case is (Primary) / DISQUALIFIED		

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

1/4 00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	papillary carcinoma, type I	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Kidney papillary renal cell carcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The tissue sample was taken at resection from a R kidney robotic partial nephrectomy with the reading pathologist stating the dx as only "papillary carcinoma, type I" and having a Fuhrman grade 2 rather than specifying it as a renal cell carcinoma, papillary type. Subsequently, the treating MD states the dx as "papillary type 1 renal cell carcinoma in the right kidney".	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 0afe2418-949c-4452-bdad-906c07974b49 (TCGA-B9-A8YH.73018C2B-3F93-4CD8-B2F7-4054EDB518AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).